Surgical pathology report (de-identified scan), TCGA case TCGA-44-2657, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2657-01A (Primary Tumor).

SPECIMEN

Left upper lobe

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass

GROSS DESCRIPTION

Received fresh in a container labeled "left upper lobe" is a wedge of lung tissue, spanning an area 10.5 x 4.3 x 3.2 cm. There is a stapled margin. The pleural surface is tan-pink, smooth, and glistening, with some anthracotic pigment deposition. The specimen is sectioned, revealing a 2.2 x 2.2 x 1.2 cm firm rubbery nodule, with minimal umbilication of the overlying pleura. The pleural surface is inked black. The lesion comes to within approximately 0.7 cm from the stapled margin, which is inked blue. The specimen outside the nodule is spongy and tan-pink, without focal lesion. RS-6. Please note that per the clinical request tissue is taken for tissue procurement.

MICROSCOPIC DESCRIPTION

The following template summarizes the findings in this case:

Histologic type: Adenocarcinoma, not otherwise characterized
Histologic grade: Moderately differentiated
Primary tumor (pT): pT2. There is focal visceral pleural invasion (block #2).
Margins of resection: Negative
Direct extension of tumor: Visceral pleural invasion
Vascular invasion: Not definitively identified
Regional lymph nodes (pN): pNX
Distant metastasis (pM): pMX
Other findings: Focal fibrosis

MICROSCOPIC DESCRIPTION

4

DIAGNOSIS

Lung, left upper lobe, wedge resection
- Moderately differentiated adenocarcinoma, with focal visceral pleural invasion, margins negative for malignancy (see microscopic description).

Source: NCI Genomic Data Commons file 6f7b097a-3c5f-4f4d-8bab-4cac117688c8 (TCGA-44-2657.D31FA48B-949C-48B7-BC78-6954EDE98172.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).